Somatic mutation profile of tumor specimen TCGA-C5-A8XK-01A (aliquot TCGA-C5-A8XK-01A-11D-A37N-09) from TCGA case TCGA-C5-A8XK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; Tumor grade: G3; Age at diagnosis: 30.9 years (11,268 days).
Specimen TCGA-C5-A8XK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db94fe09-be24-4d31-88e7-7edc6edae559.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A8XK-10A (Blood Derived Normal), aliquot TCGA-C5-A8XK-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/386bc19f-734b-411a-a191-98da648c7331

The open-access MAF lists 243 somatic variants for this specimen: 165 protein-altering or splice-affecting, 73 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 148, Silent 73, Nonsense Mutation 10, Frame Shift Ins 2, Frame Shift Del 2, 3'UTR 2, 5'UTR 1, In Frame Del 1, Nonstop Mutation 1, Intron 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 27/78 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA3 | c.3345C>G p.F1115L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100068488; called by muse, mutect2, varscan2
- ABCF3 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.166); catalogued as COSV53053385, COSV99491452; called by muse, mutect2, varscan2
- ABCF3 | c.1932G>C p.E644D | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV99491454; called by muse, mutect2, varscan2
- ACBD3 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.932); catalogued as COSV100830999; called by muse, mutect2, varscan2
- ADAMTS18 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs145596475, COSV51399037, COSV99273948; called by muse, mutect2, varscan2
- AFF2 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV99664037; called by muse, mutect2, varscan2
- ALG8 | c.484C>G p.H162D | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100220095, COSV55203509; called by muse, mutect2, varscan2
- ALMS1 | c.2638C>G p.L880V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.202); catalogued as COSV100042489; called by muse, mutect2, varscan2
- AMIGO1 | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs757591436, COSV100880979; called by muse, mutect2, varscan2
- AP3B1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV54877546; called by muse, mutect2, varscan2
- ARHGAP18 | c.997G>C p.D333H | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1172631163, COSV100936172; called by muse, mutect2, varscan2
- ARHGEF18 | c.906G>C p.E302D (on ENST00000359920 / NM_001130955.2; = p.E198D on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs775135579, COSV100149521; called by muse, mutect2, varscan2
- ATXN2L | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.124); catalogued as COSV100294332, COSV57371067; called by muse, mutect2, varscan2
- BEST1 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV99861311; called by muse, mutect2, varscan2
- BMP1 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs1037116854, COSV100109565; called by muse, mutect2, varscan2
- BNC2 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV101033258; called by muse, mutect2, varscan2
- BOLA1 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100975401; called by muse, mutect2, varscan2
- BPIFC | c.900C>A p.F300L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.103); catalogued as COSV100301054; called by muse, mutect2
- C17orf75 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV99858649; called by muse, mutect2, varscan2
- CACNA2D3 | c.653A>G p.K218R | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV99873602; called by muse, mutect2, varscan2
- CCDC88A | c.1135G>C p.E379Q | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.259); catalogued as COSV55061795, COSV99710448; called by muse, mutect2, varscan2
- CD163L1 | c.1025G>A p.R342K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100550092; called by muse, mutect2, varscan2
- CDH15 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1475336062, COSV99228395; called by muse, mutect2, varscan2
- CDH5 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV100439234; called by muse, mutect2, varscan2
- CEACAM20 | c.495C>G p.I165M | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100386861, COSV100386892; called by muse, mutect2, varscan2
- CLCNKA | c.1723G>A p.D575N | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV100510098; called by muse, mutect2, varscan2
- CLEC4F | c.1555T>G p.F519V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99713722; called by muse, mutect2, varscan2
- CLPS | c.338G>C p.*113Sext*42 | Nonstop Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV99463606, COSV99463707; called by muse, mutect2, varscan2
- COL2A1 | c.3874G>C p.E1292Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.099); catalogued as COSV100476476, COSV61531316, COSV61533436; called by muse, mutect2, varscan2
- CRTC2 | c.1483C>G p.L495V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV100339063; called by muse, mutect2, varscan2
- CRX | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.455); catalogued as COSV55756948; called by muse, mutect2, varscan2
- CSF2RB | c.2311C>G p.P771A | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.335); catalogued as COSV99453888; called by muse, mutect2, varscan2
- CYB5R4 | c.570C>G p.I190M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV100859686; called by muse, mutect2, varscan2
- CYP2A13 | c.1337G>A p.R446K | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.164); catalogued as COSV57838301; called by muse, mutect2, varscan2
- CYP7A1 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV100052374, COSV100052706; called by muse, mutect2, varscan2
- DAZAP1 | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99245234; called by muse, mutect2, varscan2
- DCHS1 | c.8914C>T p.P2972S | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.452); catalogued as rs1198932396, COSV54997066; called by muse, mutect2, varscan2
- DCUN1D5 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 33/497 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.856); catalogued as COSV99499091; called by muse, mutect2
- DHX9 | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62362559; called by muse, mutect2
- DNAH10 | c.5833G>C p.D1945H (on ENST00000409039; = p.D1884H on NM_207437.3) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101292264, COSV69000857, COSV69004213; called by muse, mutect2, varscan2
- DPY19L3 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.794); catalogued as COSV100639192; called by muse, mutect2, varscan2
- DSC2 | c.2324G>C p.G775A | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV99199643; called by muse, mutect2, varscan2
- EPG5 | c.6715G>C p.E2239Q | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV56356829; called by muse, mutect2, varscan2
- FLG | c.3773C>A p.S1258* | Nonsense Mutation (SNP) | VAF 40/110 reads (36%) | catalogued as rs1438692967, COSV100911589; called by muse, varscan2
- FRAS1 | c.5119G>A p.E1707K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99352051; called by muse, mutect2, varscan2
- FSCN1 | c.178G>C p.V60L | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV100435160, COSV61018446; called by muse, mutect2, varscan2
- FTSJ3 | c.514C>G p.Q172E | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.853); catalogued as COSV100037317; called by muse, mutect2, varscan2
- GCC2 | c.2719G>C p.E907Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.198); catalogued as COSV100565449; called by muse, mutect2, varscan2
- GLIS2 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99267531; called by muse, mutect2, varscan2
- GOLGA3 | c.3265G>A p.E1089K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748744472, COSV52626115; called by muse, mutect2, varscan2
- GON4L | c.4769G>A p.R1590Q | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776448753, COSV99674299; called by muse, mutect2, varscan2
- GON4L | c.2818G>C p.E940Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.432); catalogued as COSV55199455; called by muse, mutect2, varscan2
- GPATCH8 | c.197G>A p.R66K | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100132658; called by muse, mutect2, varscan2
- GRK6 | c.1699G>A p.D567N (on ENST00000355472 / NM_001004106.3; = p.A567= on NM_002082.3) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.068); catalogued as rs748162611, COSV62683367; called by muse, mutect2, varscan2
- HCN1 | c.1631delinsAG p.L544Qfs*13 | Frame Shift Ins (INS) | VAF 14/115 reads (12%) | catalogued as COSV57540586; called by mutect2*, pindel, varscan2*
- HECTD4 | c.8348G>A p.R2783Q | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760602252, COSV101107511; called by muse, mutect2, varscan2
- HERC1 | c.14287G>C p.E4763Q | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.328); catalogued as COSV101496570; called by muse, mutect2, varscan2
- HERPUD2 | c.759G>A p.M253I | Missense Mutation (SNP) | VAF 35/40 reads (88%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100257961; called by muse, mutect2, varscan2
- HFM1 | c.1762G>A p.A588T | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99645995; called by muse, mutect2
- HRG | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV99214790; called by muse, mutect2, varscan2
- IGHV1-24 | c.232A>G p.I78V | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs183704154; called by muse, mutect2, varscan2
- IL17RE | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV55967646, COSV55971788; called by muse, mutect2
- INCENP | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as rs770503094, COSV99611044; called by muse, mutect2, varscan2
- KCNIP2 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.18); catalogued as COSV99493385; called by muse, mutect2, varscan2
- KMT2D | c.6926C>A p.S2309* | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as COSV56421807, COSV99981350; called by muse, mutect2, varscan2
- KNTC1 | c.5278G>A p.E1760K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs775432207, COSV100338333; called by muse, varscan2
- LAMC1 | c.4663G>C p.D1555H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV99279602; called by muse, mutect2, varscan2
- LRRC19 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV101195794; called by muse, mutect2, varscan2
- MAML1 | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV52983368, COSV99483106; called by muse, mutect2, varscan2
- MAML2 | c.3145C>G p.L1049V | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV101594112; called by muse, mutect2, varscan2
- MAP4K4 | c.638G>C p.R213T | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.559); catalogued as COSV100154758; called by muse, mutect2, varscan2
- MAPK13 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV52983849; called by muse, mutect2, varscan2
- MCF2 | c.2654C>T p.S885F | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as COSV100644787, COSV58482908; called by muse, mutect2, varscan2
- MDN1 | c.10331C>T p.S3444L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs765107375, COSV65517066, COSV65517530; called by muse, mutect2, varscan2
- MICAL3 | c.2992G>C p.E998Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.968); catalogued as COSV101269743; called by muse, mutect2, varscan2
- MPDZ | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777301563, COSV59943185; called by mutect2, varscan2
- MPHOSPH9 | c.2192C>G p.S731* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as rs750477708, COSV100186804; called by muse, mutect2, varscan2
- MS4A5 | c.355A>G p.I119V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as rs757892519, COSV100281004; called by mutect2, varscan2
- MYCL | c.388G>A p.D130N (on ENST00000372816 / NM_001033081.3; = p.D160N on NM_005376.5) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV100862313, COSV100862338; called by muse, mutect2, varscan2
- MYF6 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.448); catalogued as COSV99952816; called by muse, mutect2, varscan2
- MYO6 | c.1534C>G p.Q512E | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV100889351, COSV64118587; called by muse, mutect2, varscan2
- MYOCD | c.1514C>T p.S505F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.218); catalogued as COSV100590764; called by muse, mutect2, varscan2
- NBAS | c.2530G>T p.D844Y | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV99869753; called by muse, mutect2, varscan2
- NELFE | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV100952735; called by muse, mutect2, varscan2
- NELFE | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.074); catalogued as COSV100952736, COSV64810060; called by muse, mutect2, varscan2
- NELFE | c.335G>C p.R112T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); catalogued as COSV100952738; called by muse, varscan2
- NES | c.4738C>T p.Q1580* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100957867; called by muse, mutect2, varscan2
- NUP214 | c.3585G>C p.K1195N | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV100845287; called by muse, mutect2, varscan2
- OR2A12 | c.458T>G p.L153R | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV101283169, COSV101283196; called by muse, mutect2, varscan2
- OR2W1 | c.86G>C p.G29A | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.983); catalogued as rs189250244, COSV101013909; called by muse, mutect2, varscan2
- PABPC1 | c.195G>A p.A65= | Splice Region (SNP) | VAF 14/32 reads (44%) | catalogued as rs751412519, COSV59401994; called by muse, mutect2, varscan2
- PCDHAC1 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.299); catalogued as COSV53852424, COSV99165932; called by muse, mutect2, varscan2
- PCDHB8 | c.1159C>T p.Q387* | Nonsense Mutation (SNP) | VAF 22/105 reads (21%) | catalogued as COSV50761908; called by muse, mutect2, varscan2
- PEX5L | c.1348G>C p.D450H | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99828764; called by muse, mutect2, varscan2
- PGAP1 | c.1484T>C p.L495P | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100698196; called by muse, mutect2
- PHF3 | c.1343C>T p.S448L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV100013368, COSV50312881; called by muse, mutect2, varscan2
- PKP4 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV101080952; called by muse, mutect2, varscan2
- PLBD1 | c.1504C>T p.Q502* | Nonsense Mutation (SNP) | VAF 18/73 reads (25%) | catalogued as COSV99554536; called by muse, mutect2, varscan2
- PMFBP1 | c.1756G>T p.D586Y (on ENST00000537465; = p.D581Y on NM_031293.3) | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs1436653279, COSV52824529, COSV99400898; called by muse, mutect2, varscan2
- PRDM16 | c.3044G>A p.R1015H | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758654133, COSV99576663; called by muse, mutect2, varscan2
- PRUNE2 | c.3154G>A p.E1052K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100944571; called by muse, mutect2, varscan2
- RAD21 | c.1702C>T p.Q568* | Nonsense Mutation (SNP) | VAF 15/27 reads (56%) | catalogued as COSV52063028; called by muse, mutect2, varscan2
- RAPGEFL1 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.99); catalogued as rs371505694; called by muse, varscan2
- RBM19 | c.2395G>A p.V799M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as rs1252351010, COSV99926098; called by muse, mutect2, varscan2
- RELN | c.8306T>A p.I2769N | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100633759; called by muse, mutect2, varscan2
- RFWD3 | c.2198G>A p.S733N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV100736239; called by muse, mutect2, varscan2
- RFX1 | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV99586082; called by muse, mutect2, varscan2
- RHBDD1 | c.429C>G p.F143L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100391820; called by muse, mutect2, varscan2
- RHOXF1 | c.124C>G p.P42A | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0.094); catalogued as COSV99483818, COSV99483900; called by muse, mutect2, varscan2
- RMND5B | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as rs763429428, COSV100523265; called by muse, mutect2, varscan2
- RPL32 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.219); catalogued as COSV55989529; called by muse, mutect2, varscan2
- SACS | c.8810C>T p.S2937F | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0.05); PolyPhen benign (0.259); catalogued as COSV101207450; called by muse, mutect2, varscan2
- SDK2 | c.5513C>G p.S1838C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101167655, COSV66181636; called by muse, mutect2, varscan2
- SERPINE3 | c.921C>G p.F307L | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.287); catalogued as COSV101246434; called by muse, mutect2, varscan2
- SHC1 | c.1069G>A p.E357K (on ENST00000368445 / NM_183001.5; = p.E247K on NM_003029.5) | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.231); catalogued as COSV100821070; called by muse, mutect2, varscan2
- SHC1 | c.880G>C p.E294Q (on ENST00000368445 / NM_183001.5; = p.E184Q on NM_003029.5) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100820964, COSV63535050; called by muse, mutect2, varscan2
- SLC12A8 | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1471863132, COSV100102385; called by muse, mutect2
- SLC18A3 | c.287A>G p.N96S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV100340164; called by muse, mutect2, varscan2
- SLC6A4 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99911377; called by muse, mutect2, varscan2
- SLC6A7 | c.611G>A p.S204N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100046293; called by muse, mutect2, varscan2
- SLC7A8 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1404757097, COSV100382367; called by muse, varscan2
- SLC8A1 | c.913G>C p.D305H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs746896227, COSV60483684; called by muse, varscan2
- SLC9A2 | c.992C>G p.S331* | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | catalogued as COSV52138341, COSV99296265; called by muse, mutect2, varscan2
- SMC6 | c.2374G>C p.E792Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV100705107; called by muse, mutect2, varscan2
- SPATA31D1 | c.3749G>T p.G1250V | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.501); catalogued as COSV100782790; called by muse, mutect2, varscan2
- SSH1 | c.1444G>C p.E482Q | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as COSV100425528; called by muse, mutect2, varscan2
- STARD10 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs760513932, COSV100600438, COSV100600489; called by mutect2, varscan2
- STK11 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.071); catalogued as COSV58825094, COSV58826380; called by muse, mutect2, varscan2
- STK11 | c.1123G>C p.E375Q | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.099); catalogued as COSV99289606, COSV99289712; called by muse, mutect2, varscan2
- TACO1 | c.258G>C p.L86F | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as COSV99366492; called by muse, mutect2, varscan2
- TAP1 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs777683307, COSV100841206; called by muse, mutect2, varscan2
- TBCK | c.1933G>A p.D645N (on ENST00000273980 / NM_001163436.4; = p.D582N on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99912522; called by muse, mutect2, varscan2
- TET1 | c.2647G>T p.D883Y | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV101018252, COSV65383795; called by muse, mutect2, varscan2
- TLN1 | c.1636C>G p.Q546E | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as rs906153024, COSV100147744; called by muse, mutect2, varscan2
- TNFRSF11A | c.1580G>A p.G527E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99500224, COSV99500285; called by muse, mutect2, varscan2
- TRHDE | c.934G>C p.E312Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.629); catalogued as COSV99670855; called by muse, mutect2, varscan2
- TRIM41 | c.1075C>T p.Q359* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100163266; called by muse, mutect2
- TRIT1 | c.881C>G p.T294S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV100381526; called by muse, mutect2, varscan2
- TTC21B | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs1311972479, COSV99692323; called by muse, mutect2, varscan2
- TUBB2A | c.1327G>C p.D443H | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.861); catalogued as rs1219133161, COSV100373888; called by muse, varscan2
- TUBB2A | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100373730; called by muse, varscan2
- UQCRH | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100295572; called by muse, mutect2, varscan2
- USP1 | c.2258C>G p.S753C | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.24); catalogued as COSV99224437; called by muse, mutect2, varscan2
- VPS13A | c.9391G>A p.E3131K | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.983); catalogued as COSV100818527; called by muse, mutect2, varscan2
- VWF | c.6708C>G p.F2236L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99779091; called by muse, mutect2, varscan2
- WNK2 | c.5200G>C p.G1734R (on ENST00000297954 / NM_001282394.1; = p.G1697R on NM_006648.3) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.296); catalogued as COSV99942402; called by muse, mutect2, varscan2
- XKRX | c.808G>T p.V270L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100139681; called by muse, mutect2, varscan2
- ZBTB4 | c.2860G>C p.D954H | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV100043557; called by muse, mutect2, varscan2
- ZCCHC7 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.481); catalogued as COSV100383136; called by muse, mutect2, varscan2
- ZNF281 | c.1076G>C p.R359T | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV104399328, COSV99664311; called by muse, mutect2, varscan2
- ZNF302 | c.1144C>T p.H382Y (on ENST00000627982; = p.H303Y on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101416495; called by muse, mutect2, varscan2
- ZNF594 | c.1206A>C p.K402N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV101280490; called by muse, mutect2, varscan2
- ZNF629 | c.2024C>T p.S675F | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as COSV99354803; called by muse, mutect2, varscan2
- ZNF677 | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100447938, COSV61720761; called by muse, mutect2, varscan2
- ZNF8 | c.400C>G p.P134A | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.87); PolyPhen benign (0.039); catalogued as COSV99544322; called by muse, mutect2, varscan2
- ZNF804A | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.212); catalogued as COSV100167933, COSV100168596; called by muse, varscan2
- ZNF813 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV101124853; called by muse, mutect2, varscan2
- ZSWIM8 | c.3590G>A p.G1197E (on ENST00000605216 / NM_001242487.2; = p.G1202E on NM_015037.3) | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV100013990; called by muse, mutect2, varscan2
- ALDOB | c.1052del p.A351Vfs*22 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | called by mutect2, pindel, varscan2
- CACNA1E | c.3248C>G p.S1083* | Nonsense Mutation (SNP) | VAF 4/8 reads (50%) | called by muse, mutect2
- ERC1 | c.474del p.K159Rfs*4 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | called by mutect2, pindel, varscan2
- HCN1 | c.1632dup p.T545Dfs*12 | Frame Shift Ins (INS) | VAF 21/111 reads (19%) | called by mutect2, varscan2
- HLA-C | c.487_501del p.A163_T167del | In Frame Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- IGLV4-3 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, varscan2
- ABCF3 | c.1980G>A p.V660= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV53052827; called by muse, mutect2, varscan2
- ADGRE3 | c.1029C>T p.V343= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV99506215; called by muse, mutect2, varscan2
- ADGRV1 | c.5937C>T p.F1979= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV101315975; called by muse, mutect2, varscan2
- ANKRD35 | c.1860G>A p.L620= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV100841736; called by muse, mutect2, varscan2
- ARID1B | c.5250C>T p.I1750= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs533990759, COSV99269186; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARSI | c.153C>T p.F51= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs746230231, COSV100155980; called by muse, varscan2
- C1orf158 | c.438C>G p.L146= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as COSV55347741; called by muse, mutect2, varscan2
- CEACAM6 | c.819C>T p.I273= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV99555570; called by muse, mutect2, varscan2
- CFAP157 | c.48C>G p.V16= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV100076884; called by muse, mutect2, varscan2
- CLASRP | c.30G>T p.R10= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV99672913; called by muse, mutect2, varscan2
- CNNM2 | c.246G>A p.T82= | Silent (SNP) | VAF 42/106 reads (40%) | catalogued as rs1293542670, COSV100881723; called by muse, mutect2, varscan2
- COL6A3 | c.6393G>T p.G2131= | Silent (SNP) | VAF 24/40 reads (60%) | catalogued as COSV99798328; called by muse, mutect2, varscan2
- DGKG | c.1632G>C p.L544= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV99403308; called by muse, mutect2, varscan2
- DTX4 | c.243C>T p.Y81= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs370390470; called by muse, varscan2
- DYRK2 | c.960C>T p.F320= (on ENST00000344096 / NM_006482.3; = p.F247= on NM_003583.4) | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs1001100183, COSV100165309; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.780G>A p.V260= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV100349140; called by muse, mutect2, varscan2
- ESRP1 | c.1128C>T p.L376= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV100619320; called by muse, mutect2, varscan2
- FAM241B | c.285C>T p.L95= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs1030535176, COSV64768497; called by muse, mutect2, varscan2
- FCGBP | c.8655C>T p.F2885= | Silent (SNP) | VAF 24/182 reads (13%) | catalogued as rs1455742229; called by muse, mutect2, varscan2
- FER | c.1938C>T p.L646= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs1013129759, COSV99812812; called by muse, mutect2, varscan2
- FLG | c.3687C>T p.G1229= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV100911590, COSV64250413; called by muse, mutect2, varscan2
- GLI4 | c.933C>T p.I311= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV60681635, COSV60682249; called by muse, mutect2, varscan2
- GTF2H3 | c.912G>A p.L304= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV99967574; called by muse, mutect2, varscan2
- IGF2R | c.6882G>A p.Q2294= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs144961874; called by muse, mutect2, varscan2
- INTS3 | c.2280G>A p.L760= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100016013; called by muse, mutect2, varscan2
- KCNJ12 | c.36C>T p.I12= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs567413846, COSV59164690, COSV59176050; called by muse, mutect2
- KIF26B | c.3630C>A p.I1210= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV100832418; called by muse, mutect2, varscan2
- KIF26B | c.3777C>T p.L1259= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100832421; called by muse, mutect2, varscan2
- LAG3 | c.537C>T p.L179= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV99179937; called by muse, mutect2, varscan2
- LRIG2 | c.876C>G p.L292= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs1327260242, COSV63163265; called by muse, mutect2, varscan2
- MEF2D | c.535C>T p.L179= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100559968, COSV61728469; called by muse, mutect2, varscan2
- MEIS1 | c.258C>G p.L86= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV55484268, COSV99715220; called by muse, mutect2, varscan2
- MTMR12 | c.1626G>C p.V542= | Silent (SNP) | VAF 10/180 reads (6%) | catalogued as COSV99373604; called by muse, mutect2
- MYH14 | c.945C>G p.L315= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV99222729; called by muse, mutect2, varscan2
- NR3C1 | c.1674G>A p.R558= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as rs927474837, COSV99196309; called by muse, mutect2, varscan2
- NUDT13 | c.771G>A p.L257= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV100624769; called by muse, mutect2, varscan2
- OBSCN | c.15588C>G p.V5196= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV99478143; called by muse, mutect2, varscan2
- ODF2 | c.300C>G p.V100= (on ENST00000434106 / NM_153433.2; = p.V76= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV100654639; called by muse, mutect2, varscan2
- OGDHL | c.924G>A p.V308= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV100934326; called by muse, varscan2
- OR11H4 | c.789G>A p.G263= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV100197518; called by muse, mutect2, varscan2
- PATJ | c.960C>G p.V320= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100334214; called by muse, mutect2, varscan2
- PGAP1 | c.1486C>T p.L496= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV100698195; called by muse, mutect2
- PHC1 | c.2274G>A p.L758= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV101418607; called by muse, mutect2, varscan2
- PLIN5 | c.315C>G p.P105= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as COSV101113522; called by muse, mutect2, varscan2
- POC1B | c.1110C>T p.T370= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as COSV100544218, COSV57968581; called by muse, mutect2, varscan2
- PPARG | c.1416G>A p.Q472= (on ENST00000287820 / NM_015869.5; = p.Q442= on NM_005037.7) | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV99826510; called by muse, mutect2, varscan2
- PRAMEF7 | c.1209G>C p.L403= | Silent (SNP) | VAF 24/188 reads (13%) | called by muse, mutect2, varscan2
- PRAMEF8 | c.1209G>C p.L403= | Silent (SNP) | VAF 10/41 reads (24%) | called by mutect2, varscan2
- PRKD3 | c.108C>G p.L36= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as rs1453156778, COSV99306139; called by muse, mutect2, varscan2
- RPS27A | c.123G>A p.Q41= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99703161; called by muse, mutect2, varscan2
- SBSPON | c.438C>T p.F146= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV99817530; called by muse, mutect2, varscan2
- SCN10A | c.4725C>T p.I1575= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV101479396; called by muse, mutect2, varscan2
- SDCCAG8 | c.2076G>A p.Q692= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs1266717610, COSV100285488, COSV59414014; called by muse, mutect2, varscan2
- SLC39A13 | c.330C>G p.L110= | Silent (SNP) | VAF 25/38 reads (66%) | catalogued as COSV100712673; called by muse, mutect2, varscan2
- SLC4A4 | c.2049G>T p.G683= (on ENST00000264485 / NM_001098484.3; = p.G639= on NM_003759.4) | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV99140202; called by muse, mutect2, varscan2
- SOX4 | c.1179C>T p.G393= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV99782028; called by muse, mutect2, varscan2
- TCHH | c.2004C>G p.L668= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs572360148, COSV100915060; called by muse, varscan2
- TECR | c.924C>G p.L308= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as COSV99295087; called by muse, mutect2, varscan2
- THRA | c.528C>G p.R176= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99225510; called by mutect2, varscan2
- TMEM39B | c.504C>G p.L168= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100298011; called by muse, mutect2, varscan2
- TRIM23 | c.1410C>G p.L470= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV51549476; called by muse, mutect2, varscan2
- TRPS1 | c.2718C>G p.L906= (on ENST00000220888 / NM_001330599.2; = p.L919= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99630925; called by muse, mutect2, varscan2
- TTC4 | c.492G>C p.L164= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV100988426; called by muse, mutect2, varscan2
- TUBGCP2 | c.1884C>T p.L628= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as rs1248246633, COSV99427741; called by muse, mutect2, varscan2
- TULP4 | c.2598G>A p.K866= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV100893499; called by muse, mutect2, varscan2
- UFL1 | c.1578T>G p.T526= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV100990069; called by muse, mutect2, varscan2
- USP19 | c.2496C>T p.L832= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100026164; called by muse, mutect2, varscan2
- VPREB1 | c.36C>G p.V12= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100164834; called by muse, mutect2, varscan2
- VWA3A | c.3381G>A p.L1127= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs1387737176, COSV100240912; called by muse, mutect2, varscan2
- WDR36 | c.687G>A p.L229= | Silent (SNP) | VAF 35/127 reads (28%) | catalogued as COSV101540802; called by muse, mutect2, varscan2
- WSB2 | c.477G>C p.L159= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100199314; called by muse, mutect2, varscan2
- ZNF45 | c.885G>C p.L295= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV54194917, COSV99524142; called by muse, mutect2, varscan2
- ZNF830 | c.459C>T p.L153= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs567200907, COSV100030675; called by muse, mutect2, varscan2
- EGFR | c.1881-756G>C | Intron (SNP) | VAF 26/42 reads (62%) | catalogued as COSV51852005, COSV99291070; called by muse, mutect2, varscan2
- FAS | c.*107G>A | 3'UTR (SNP) | VAF 21/69 reads (30%) | catalogued as COSV58240073; called by muse, mutect2, varscan2
- GSTM4 | c.-1C>T | 5'UTR (SNP) | VAF 32/84 reads (38%) | catalogued as COSV100264143; called by muse, mutect2, varscan2
- LIPJ | c.*2G>A | 3'UTR (SNP) | VAF 17/44 reads (39%) | catalogued as COSV100905915; called by muse, mutect2, varscan2
- XIST | n.10587G>A | RNA (SNP) | VAF 21/57 reads (37%) | catalogued as rs867444479; called by muse, mutect2, varscan2
